Somatic mutation profile of tumor specimen BA2603D (aliquot aq-BA2603D) from BEATAML1.0 case 2314, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.8 years (23,321 days).
Specimen BA2603D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 103ded55-29d2-4173-9d9a-fa9180169463.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2635D (Solid Tissue Normal), aliquot aq-BA2635D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15c1f5ae-ccce-4a9e-9b90-96684a85305a

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 28/68 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- ARSL | c.1226C>T p.T409M | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM081159; called by mutect2, varscan2
- GJA8 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.675); catalogued as COSV53788283; called by muse, mutect2, varscan2
- HDAC6 | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557028048; called by muse, varscan2
- DGKI | c.1417T>C p.W473R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPER1 | c.521C>A p.A174D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SHISA7 | c.1092G>C p.E364D | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHEK2 | c.420G>A p.R140= | Silent (SNP) | VAF 39/66 reads (59%) | called by muse, mutect2, varscan2
- RYR3 | c.2121C>T p.D707= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs369220734; called by muse, mutect2
- ST6GALNAC1 | c.261C>T p.N87= | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as rs1288556781; called by muse, mutect2, varscan2
